Somatic mutation profile of tumor specimen BA3330D (aliquot aq-BA3330D) from BEATAML1.0 case 2165, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,137 days).
Specimen BA3330D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c21f8327-2423-4d9f-86b1-615a1cfcaf34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3032D (Solid Tissue Normal), aliquot aq-BA3032D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5f3e0f3-3bb2-4907-9398-a4079b2cd14a

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTNL9 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.102); called by muse, mutect2
- HMX2 | c.-71C>A | 5'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
